Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3979, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3979-01A (Primary Tumor).

Diagnosis:

Resected section of colon (sigma) with a colon carcinoma characterized histologically as a moderately differentiated colorectal adenocarcinoma, extending up to 5 cm to one resection margin and measuring 4.5 cm in diameter at the widest point. Invasive spread of the tumor within all intestinal wall layers up to the bordering mesocolic fatty tissue and the level of the subserosa.

In addition, the colon wall has a few pseudodiverticula and slightly scarring peridiverticulitis.

The stage of the tumor is therefore: pT3 pN0 (0/22) L0 V0; G2 R0.

Source: NCI Genomic Data Commons file 90049a40-9c67-4801-a280-63e9187728a9 (TCGA-AA-3979.3336E745-C20B-4CEF-A6FD-8E6EDC6F03A1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).